Somatic mutation profile of tumor specimen ALCH-B0E8-TTP1-A (aliquot ALCH-B0E8-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B0E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.5 years (24,665 days).
Specimen ALCH-B0E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54bebe60-94ac-44c0-94d8-b8064f56fa61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0E8-NB1-A (Blood Derived Normal), aliquot ALCH-B0E8-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/093819cc-bb7a-4403-a88f-02cf924bc0bb

The open-access MAF lists 490 somatic variants for this specimen: 340 protein-altering or splice-affecting, 94 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 300, Silent 94, Intron 32, Nonsense Mutation 16, RNA 10, Splice Site 9, Frame Shift Del 7, Splice Region 6, 5'Flank 5, 5'UTR 5, 3'UTR 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 64/441 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 57/473 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1868T>A p.L623* (on ENST00000340800 / NM_022977.2; = p.L582* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100538559, COSV61615408; called by muse, mutect2
- ADGRL3 | c.1168G>C p.V390L (on ENST00000506720 / NM_001322402.2; = p.V322L on NM_015236.6) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV72267659; called by muse, mutect2, varscan2
- ANGPT2 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 30/298 reads (10%) | catalogued as rs759993549; called by muse, mutect2
- APOB | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.077); catalogued as rs752032737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBOX1 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54191720; called by muse, mutect2
- C3orf22 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.693); catalogued as rs751488553; called by muse, mutect2
- C5AR2 | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99953796; called by muse, mutect2, varscan2
- CCT8L2 | c.1378G>C p.V460L | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs747634629, COSV100743103; called by muse, mutect2
- CHD7 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.031); catalogued as COSV101418163; called by muse, mutect2
- CHL1 | c.2450G>T p.G817V (on ENST00000397491 / NM_001253387.1; = p.G833V on NM_006614.4) | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV56586280, COSV99062470; called by muse, varscan2
- CNTNAP2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769071764, COSV62144657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99242479; called by muse, mutect2, varscan2
- CPS1 | c.2073G>T p.L691F | Missense Mutation (SNP) | VAF 70/684 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV99242249; called by muse, mutect2, varscan2
- CRACD | c.2121del p.N708Tfs*121 | Frame Shift Del (DEL) | VAF 25/200 reads (13%) | catalogued as COSV51726633; called by pindel, varscan2*
- CSMD1 | c.5977G>T p.G1993C (on ENST00000520002; = p.G1992C on NM_033225.6) | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150999; called by muse, mutect2, varscan2
- CSMD3 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 41/424 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.763); catalogued as COSV52198582, COSV52266646; called by muse, mutect2, varscan2
- CUBN | c.2377A>T p.S793C | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs767796430; called by muse, mutect2, varscan2
- CYTH2 | c.1116-1G>T p.X372_splice (on ENST00000427476; = p.X371_splice on NM_004228.7) | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as COSV99059710; called by muse, mutect2, varscan2
- DBN1 | c.331-4G>T | Splice Region (SNP) | VAF 17/214 reads (8%) | catalogued as rs1453058566; called by muse, mutect2
- DCAF12L1 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100948164; called by muse, mutect2, varscan2
- DCX | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 46/509 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57572451; called by muse, mutect2
- DMRTB1 | c.890C>G p.P297R | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768912441, COSV65112604; called by muse, mutect2, varscan2
- DNHD1 | c.9528C>A p.S3176R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs747522193; called by muse, mutect2, varscan2
- DOCK2 | c.3719C>A p.A1240D | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99909644; called by muse, mutect2
- DPYS | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100037135; called by muse, mutect2
- DUSP13 | c.*701A>G | Splice Region (SNP) | VAF 14/109 reads (13%) | catalogued as rs1473777370; called by muse, mutect2
- DUSP22 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140673019, COSV60531870; called by muse, mutect2
- DVL3 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1266047392, COSV100493595; called by muse, mutect2
- EGFLAM | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs771340804, COSV59296152; called by muse, mutect2, varscan2
- FBF1 | c.847G>A p.D283N (on ENST00000586717; = p.D297N on NM_001319193.1) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs376847537; called by muse, mutect2
- FHL5 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs750274365; called by muse, mutect2
- GASK1B | c.1329C>A p.F443L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774062128; called by muse, mutect2
- GKN1 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV65006240; called by muse, mutect2
- GPER1 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as rs779573563; called by mutect2, varscan2
- GPKOW | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1557090272, COSV50245579; called by muse, mutect2, varscan2
- H2BC5 | c.263C>G p.S88W | Missense Mutation (SNP) | VAF 38/720 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV56799581, COSV56800091; called by muse, mutect2
- HACE1 | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99493396; called by muse, mutect2
- HLX | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as rs777701429; called by muse, mutect2, varscan2
- HRH2 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51573366; called by muse, mutect2, varscan2
- HS3ST1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs368275390; called by muse, mutect2, varscan2
- HUWE1 | c.2614C>T p.R872* | Nonsense Mutation (SNP) | VAF 12/402 reads (3%) | catalogued as COSV99470838; called by muse, mutect2
- IFNL2 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs771117892; called by muse, mutect2, varscan2
- IL11RA | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 37/488 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs760384911; called by muse, mutect2
- KCNB2 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1469575222; called by muse, mutect2, varscan2
- KIAA1549L | c.3257G>A p.R1086H (on ENST00000321505; = p.R1383H on NM_012194.3) | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572642569, COSV55772555; called by muse, mutect2, varscan2
- KIR3DL2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV99552410; called by muse, mutect2, varscan2
- KL | c.1687G>T p.V563F | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs1247091110, COSV101199015; called by muse, mutect2, varscan2
- KLRF1 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV54380532; called by muse, mutect2, varscan2
- KRTAP13-3 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 34/575 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61880187; called by muse, mutect2
- KRTAP24-1 | c.676A>G p.R226G | Missense Mutation (SNP) | VAF 69/595 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.942); catalogued as rs755112045; called by muse, mutect2, varscan2
- KTI12 | c.391A>T p.S131C | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.754); catalogued as rs777503714; called by muse, mutect2
- L1CAM | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs782401498, CM099752; called by muse, mutect2, varscan2
- LINGO3 | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101347246; called by muse, mutect2
- LMX1A | c.466A>T p.S156C | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.885); catalogued as COSV54229744; called by muse, mutect2
- LRFN5 | c.2072C>G p.T691R | Missense Mutation (SNP) | VAF 31/547 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); catalogued as COSV53254589, COSV53260302; called by muse, mutect2
- LRRC6 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV51544749; called by muse, mutect2, varscan2
- MAGEB10 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 59/487 reads (12%) | catalogued as COSV63311737; called by muse, mutect2, varscan2
- MAGEC3 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53579585, COSV68923893; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 28/200 reads (14%) | catalogued as rs746398787; called by mutect2, varscan2
- MSN | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV64304831; called by muse, mutect2, varscan2
- MTUS2 | c.2285C>A p.S762* | Nonsense Mutation (SNP) | VAF 70/670 reads (10%) | catalogued as COSV70914059; called by muse, mutect2
- MYH14 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.219); catalogued as rs1233074390; called by muse, mutect2
- MYH2 | c.1430A>T p.E477V | Missense Mutation (SNP) | VAF 74/716 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV55441738; called by muse, mutect2, varscan2
- MYO18B | c.6263C>A p.A2088E | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV59145509; called by muse, mutect2
- NFATC1 | c.1588G>T p.V530F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV53705397; called by muse, mutect2, varscan2
- NGFR | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1168746522; called by muse, mutect2, varscan2
- NHS | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.039); catalogued as CM148163; called by muse, varscan2
- NKG7 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs267605610; called by muse, mutect2, varscan2
- NLRP5 | c.3241G>A p.G1081R | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921430147; called by muse, mutect2, varscan2
- NOTCH1 | c.7058G>T p.S2353I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV53049005; called by muse, mutect2
- NPBWR2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751123142, COSV63900540; called by muse, mutect2, varscan2
- OCA2 | c.1269G>T p.W423C | Missense Mutation (SNP) | VAF 92/683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62352619; called by muse, mutect2, varscan2
- OR10Z1 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV63525476; called by muse, mutect2
- OR11H1 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 45/1630 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV53271894, COSV99079123; called by muse, mutect2
- OR1N2 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs1243984599, COSV101031444; called by muse, mutect2
- OR2B2 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.441); catalogued as COSV100308000; called by muse, mutect2
- OR4P4 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1433062437; called by muse, mutect2
- OR4S2 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100412636, COSV56747003; called by muse, mutect2, varscan2
- OR52E2 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100384539; called by muse, mutect2
- OR5D13 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 34/466 reads (7%) | catalogued as COSV62334296; called by muse, mutect2
- OR6A2 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 49/491 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PCDHGB2 | c.1221C>A p.D407E | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as rs546446580, COSV53895031; called by muse, mutect2, varscan2
- PDE6B | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55325135; called by muse, mutect2, varscan2
- PHF7 | c.170T>A p.V57E | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV56234863; called by muse, mutect2
- PIGN | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62947652; called by muse, mutect2
- POTEE | c.2125G>T p.V709F | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1320568849; called by muse, varscan2
- PREX1 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV64252302; called by mutect2, varscan2
- PROM2 | c.2255G>T p.R752L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV100468909; called by muse, mutect2
- SIGLEC8 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as COSV58472389; called by muse, mutect2, varscan2
- SLC3A1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99576934; called by muse, mutect2, varscan2
- SLC6A1 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55114644; called by muse, mutect2
- SLC9A7 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766619827; called by muse, mutect2
- SMURF2 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99300843; called by muse, mutect2
- SP5 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1315604011, COSV64623288; called by muse, mutect2
- ST6GAL2 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 81/540 reads (15%) | PolyPhen probably damaging (0.966); catalogued as COSV62416729; called by muse, mutect2, varscan2
- STX18 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs139040070; called by muse, mutect2
- TACO1 | c.516-1G>A p.X172_splice | Splice Site (SNP) | VAF 63/770 reads (8%) | catalogued as rs973671414, COSV51975173; called by muse, mutect2
- TBX22 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 76/732 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV64786700; called by muse, mutect2
- THAP4 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs758983149; called by muse, mutect2, varscan2
- TTLL8 | c.504C>A p.I168= | Splice Region (SNP) | VAF 16/164 reads (10%) | catalogued as rs759477140, COSV56724925; called by muse, mutect2
- UTP20 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1220163644; called by muse, mutect2, varscan2
- WDR43 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775012174, COSV56098853; called by muse, mutect2
- ZNF304 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV56586190; called by muse, mutect2, varscan2
- ZNF570 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57579047; called by muse, mutect2
- ZNF585B | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57216356; called by muse, mutect2, varscan2
- ZNF606 | c.2080C>G p.H694D | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as COSV58706153, COSV58707030; called by muse, mutect2
- ZNF716 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as rs782307669, COSV101348746; called by muse, mutect2
- ABCB11 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.153); called by muse, mutect2
- ABCB5 | c.1712G>T p.S571I (on ENST00000404938 / NM_001163941.2; = p.S126I on NM_178559.6) | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ADAM7 | c.1571A>T p.D524V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, varscan2
- ADGRG2 | c.2044G>A p.D682N (on ENST00000379869 / NM_001079858.3; = p.D679N on NM_005756.4) | Missense Mutation (SNP) | VAF 16/523 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2
- AL445989.1 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 86/965 reads (9%) | SIFT deleterious (0.02); called by muse, mutect2
- AMER3 | c.1058G>C p.C353S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKAR | c.3608G>T p.R1203I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36C | c.4681G>T p.D1561Y | Missense Mutation (SNP) | VAF 31/527 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ANKRD36C | c.4444C>A p.H1482N | Missense Mutation (SNP) | VAF 96/838 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ARHGAP35 | c.2095A>T p.T699S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.036); called by muse, mutect2
- ARHGAP44 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2
- ARHGAP44 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2
- ARMCX5 | c.674C>A p.S225* | Nonsense Mutation (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- ARR3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP10B | c.4227G>T p.R1409S | Missense Mutation (SNP) | VAF 94/733 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCO2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- BCOR | c.3465C>A p.D1155E | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BCORL1 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- BICRA | c.4207G>T p.G1403W | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- BPIFB4 | c.1483A>G p.K495E | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- BRIP1 | c.2380-1G>T p.X794_splice | Splice Site (SNP) | VAF 43/212 reads (20%) | called by muse, mutect2, varscan2
- BRWD3 | c.2457C>A p.D819E | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BZW2 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- C10orf71 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- C1orf68 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 64/746 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2orf16 | c.1394C>A p.P465Q | Missense Mutation (SNP) | VAF 22/393 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2
- C4orf51 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN6 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.012); called by muse, mutect2
- CCNB3 | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCT8L2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by muse, varscan2
- CDC123 | c.23_24insAAGCA p.H8Qfs*29 | Frame Shift Ins (INS) | VAF 38/420 reads (9%) | called by mutect2, pindel
- CDH26 | c.681_688del p.R228Wfs*6 | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel
- CEACAM3 | c.132T>A p.S44R | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CFAP47 | c.4707G>T p.M1569I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP47 | c.9232G>A p.E3078K | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CLEC3A | c.143-1G>T p.X48_splice (on ENST00000651443; = p.X39_splice on NM_005752.6) | Splice Site (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- CNTNAP2 | c.1974C>A p.Y658* | Nonsense Mutation (SNP) | VAF 61/822 reads (7%) | called by muse, mutect2
- CNTNAP4 | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- COL1A2 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 72/877 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- COL5A2 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 89/1060 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL7A1 | c.6580G>C p.A2194P | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.09); called by muse, mutect2
- COL7A1 | c.5768A>T p.E1923V | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CPA1 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- CSMD2 | c.2387+2T>C p.X796_splice | Splice Site (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1409C>G p.P470R | Missense Mutation (SNP) | VAF 54/462 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.4265G>T p.G1422V (on ENST00000597505 / NM_001367979.1; = p.G529V on NM_020869.3) | Missense Mutation (SNP) | VAF 50/522 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- DCDC1 | c.1986A>C p.V662= | Splice Region (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
- DCHS1 | c.1910A>T p.D637V | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- DEGS1 | c.913A>T p.T305S | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- DENND5A | c.3009G>T p.Q1003H | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DICER1 | c.5599T>C p.F1867L | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- DLGAP4 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DQX1 | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DSG1 | c.2759T>C p.V920A | Missense Mutation (SNP) | VAF 73/724 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- EEFSEC | c.994A>T p.K332* | Nonsense Mutation (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- EFCAB8 | c.1857G>T p.L619= | Splice Region (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- ENTPD1 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 64/647 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- EPHX3 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ERVV-2 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ESPL1 | c.1679G>C p.G560A | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- EVPL | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXOC3L2 | c.1931C>A p.T644N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.434); called by muse, mutect2
- EXOC5 | c.463A>T p.K155* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | called by muse, varscan2
- F11 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 57/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- F13A1 | c.1380C>A p.H460Q | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2
- FAAH2 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FABP4 | c.373T>G p.S125A | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FAM122B | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 52/533 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- FAM170A | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- FAM47B | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FAT3 | c.13138G>T p.G4380W | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2
- FAT3 | c.13328C>A p.A4443D | Missense Mutation (SNP) | VAF 43/503 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- FCRL4 | c.282C>A p.N94K | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FOCAD | c.3949-2A>T p.X1317_splice | Splice Site (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- FOXA2 | c.26G>A p.G9E (on ENST00000377115 / NM_153675.3; = p.G15E on NM_021784.5) | Missense Mutation (SNP) | VAF 37/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FZD10 | c.1366A>C p.T456P | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GABRB3 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 24/359 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- GAL3ST3 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GIT1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.085); called by muse, mutect2
- GNL2 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- GNL3L | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GOLGA4 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GOLGA6L6 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 34/738 reads (5%) | SIFT tolerated (0.22); called by muse, mutect2
- GOT1L1 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.732); called by muse, mutect2
- GPC3 | c.908T>A p.L303H | Missense Mutation (SNP) | VAF 67/672 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR26 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.225); called by muse, mutect2
- GPRC6A | c.842T>A p.F281Y | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GRIN2B | c.1457A>C p.H486P | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.2692G>T p.G898C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HDAC9 | c.2948A>G p.D983G | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2
- HPSE2 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ICE1 | c.2958G>T p.Q986H | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGBP1P2 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGSF1 | c.3347G>T p.R1116M | Missense Mutation (SNP) | VAF 69/684 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IGSF1 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL17B | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INAVA | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IRGQ | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ITIH5 | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- JPH3 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KCNA10 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 15/395 reads (4%) | called by muse, mutect2
- KCNJ12 | c.284G>C p.W95S | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1210 | c.4343C>A p.S1448Y | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KIF7 | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KLHL34 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KREMEN1 | c.1304G>T p.G435V (on ENST00000407188; = p.G437V on NM_032045.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- KRT222 | c.657del p.Q220Rfs*23 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP7-1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 25/544 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMB4 | c.3961G>C p.A1321P | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- LILRA1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LONRF3 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- LRP2 | c.13388+1G>T p.X4463_splice | Splice Site (SNP) | VAF 92/706 reads (13%) | called by muse, mutect2, varscan2
- LRRC66 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2
- MAGEA11 | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAGEB16 | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- MAOA | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MCM3AP | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- MCM3AP | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- MED14 | c.3872G>C p.G1291A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.404); called by muse, mutect2
- METTL14 | c.503+1G>A p.X168_splice | Splice Site (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- METTL7B | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MFGE8 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM2 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MORC4 | c.2189C>A p.P730Q | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2
- MUC16 | c.11849C>G p.T3950R | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MYO18B | c.1513-4T>A | Splice Region (SNP) | VAF 29/384 reads (8%) | called by muse, mutect2
- MYO9A | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAP1L3 | c.626T>A p.V209D | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.4337G>C p.R1446P | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCEH1 | c.254T>C p.L85P (on ENST00000538775; = p.L53P on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NCL | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NCOA2 | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 93/747 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEK9 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2
- NLRP11 | c.1300A>T p.N434Y | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); called by muse, mutect2
- NPAS2 | c.848C>G p.S283* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- NPAS3 | c.1302-1G>T p.X434_splice (on ENST00000356141 / NM_001164749.2; = p.X402_splice on NM_022123.3) | Splice Site (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- NPLOC4 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); called by muse, mutect2
- OCA2 | c.2335G>T p.G779* | Nonsense Mutation (SNP) | VAF 62/427 reads (15%) | called by muse, mutect2, varscan2
- OLFML2B | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52E2 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OR5D16 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8J3 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.114); called by muse, mutect2
- OSR1 | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2
- PAMR1 | c.1256A>T p.Y419F (on ENST00000619888 / NM_001001991.3; = p.Y436F on NM_015430.4) | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCARE | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.2375C>A p.A792D | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PCNT | c.8175G>T p.E2725D | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIK3C3 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- PKHD1 | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 42/555 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2
- PLAAT5 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLEKHG5 | c.2368G>T p.D790Y (on ENST00000400915 / NM_001042663.3; = p.D753Y on NM_020631.6) | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PNCK | c.326C>A p.T109K (on ENST00000340888 / NM_001366975.1; = p.T192K on NM_001039582.3) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- PNMA3 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- POTEE | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- PPP1R18 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- PRKAG2 | c.1217A>C p.K406T | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- PRKCB | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- PRSS12 | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 69/646 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTCH2 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB12 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.354); called by muse, mutect2
- REPS2 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 37/404 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2
- RGPD3 | c.4952C>A p.T1651N | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RIMS2 | c.1510G>T p.G504C (on ENST00000666250 / NM_001348490.2; = p.G312C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/768 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROCK2 | c.1098A>T p.E366D | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ROR2 | c.1804G>T p.G602W | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPRD2 | c.3419A>T p.N1140I | Missense Mutation (SNP) | VAF 32/525 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2
- RREB1 | c.4450A>T p.R1484W | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RRM1 | c.1635C>G p.D545E | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH4A | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSRC1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.023); called by muse, mutect2
- RYR2 | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SCFD2 | c.485del p.P162Lfs*8 | Frame Shift Del (DEL) | VAF 42/462 reads (9%) | called by mutect2, pindel
- SCN7A | c.2060del p.G687Efs*4 | Frame Shift Del (DEL) | VAF 49/456 reads (11%) | called by mutect2, pindel, varscan2
- SEMA3E | c.855C>A p.S285R | Missense Mutation (SNP) | VAF 44/503 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- SIRPA | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SLC12A1 | c.2028C>G p.H676Q | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A11 | c.1513A>T p.S505C | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC27A1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.184); called by muse, mutect2
- SLC6A4 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK2 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2
- SLITRK3 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SNTG1 | c.1332T>A p.D444E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SRCAP | c.9575G>T p.G3192V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SRPX2 | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 48/590 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- SSH1 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- STK39 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3089A>C p.K1030T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.745); called by mutect2, varscan2
- STON2 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); called by muse, mutect2
- STOX1 | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by mutect2, varscan2
- SULT1C4 | c.58A>C p.N20H | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SVOP | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- SYCP2 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SYT8 | c.1151G>C p.R384P | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); called by muse, mutect2
- TADA2B | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TAS1R2 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D2 | c.1572A>T p.E524D | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- TBC1D8B | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- TCAIM | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TEDC1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- THOC2 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM106B | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM161B | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TMPRSS9 | c.3095C>A p.P1032Q (on ENST00000648592; = p.P998Q on NM_182973.2) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMTC1 | c.838C>A p.P280T (on ENST00000539277 / NM_001193451.2; = p.P172T on NM_175861.3) | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2
- TRAK2 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 42/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC17 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TTC17 | c.1449G>T p.W483C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.36); called by muse, mutect2
- TTC36 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2
- UBE2H | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- UBN2 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- UNC79 | c.1193A>G p.N398S (on ENST00000393151 / NM_001346218.2; = p.N221S on NM_020818.5) | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- USH2A | c.10144G>T p.V3382F | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP54 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 54/772 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2
- VASH1 | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- VCAN | c.7195A>T p.T2399S | Missense Mutation (SNP) | VAF 47/468 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VWA5A | c.2268G>A p.M756I | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- WDR6 | c.1915G>A p.V639M | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- WIPF1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 44/509 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBED1 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ZDBF2 | c.3662T>C p.I1221T | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF16 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF185 | c.1072del p.R358Gfs*8 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | called by mutect2, pindel, varscan2
- ZNF451 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF521 | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ZNF585B | c.1914G>T p.E638D | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- ZNF615 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF644 | c.3815G>C p.G1272A (on ENST00000337393 / NM_201269.3; = p.G50A on NM_016620.3) | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF729 | c.2909del p.G970Afs*43 | Frame Shift Del (DEL) | VAF 19/154 reads (12%) | called by mutect2, varscan2
- ZNF735 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- ZNF778 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF786 | c.1772G>C p.R591T | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- AHNAK2 | c.13248G>A p.E4416= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV60928819; called by muse, mutect2, varscan2
- ALG3 | c.24C>A p.R8= | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- AQP5 | c.597C>T p.F199= | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- ARHGAP4 | c.2574A>T p.P858= | Silent (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- ARSF | c.606C>A p.T202= | Silent (SNP) | VAF 63/611 reads (10%) | called by muse, mutect2, varscan2
- ATP4A | c.2805C>T p.I935= | Silent (SNP) | VAF 40/409 reads (10%) | catalogued as rs776219773; called by muse, mutect2
- BNC2 | c.2217A>G p.E739= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- C1orf53 | c.192G>A p.A64= | Silent (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- CACNA1B | c.3144C>T p.L1048= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as COSV53115147; called by muse, mutect2
- CARD11 | c.2481G>T p.L827= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- CFAP73 | c.6G>T p.A2= | Silent (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- CNGA2 | c.1017G>T p.G339= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV61703611; called by muse, mutect2, varscan2
- COL22A1 | c.3051A>G p.A1017= | Silent (SNP) | VAF 42/487 reads (9%) | catalogued as COSV57323200; called by muse, mutect2
- CUBN | c.9042G>T p.L3014= | Silent (SNP) | VAF 100/960 reads (10%) | catalogued as COSV100912709; called by muse, mutect2, varscan2
- DCDC1 | c.5172G>A p.E1724= (on ENST00000597505 / NM_001367979.1; = p.E831= on NM_020869.3) | Silent (SNP) | VAF 44/564 reads (8%) | catalogued as COSV57998242; called by muse, mutect2
- DCDC1 | c.4089C>A p.V1363= (on ENST00000597505 / NM_001367979.1; = p.V470= on NM_020869.3) | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as COSV57998498; called by muse, mutect2
- DDX11 | c.274C>T p.L92= | Silent (SNP) | VAF 105/559 reads (19%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13533G>T p.L4511= | Silent (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- ELFN1 | c.1113G>T p.L371= | Silent (SNP) | VAF 28/316 reads (9%) | called by muse, mutect2
- EPHB6 | c.2403C>T p.S801= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs756316909, COSV63892322; called by muse, mutect2
- EPX | c.102G>A p.S34= | Silent (SNP) | VAF 58/614 reads (9%) | catalogued as rs755155930; called by muse, mutect2
- FAAH2 | c.366C>A p.P122= | Silent (SNP) | VAF 18/308 reads (6%) | catalogued as rs769027792; called by muse, mutect2
- FAM184B | c.2355C>A p.G785= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2
- FAT3 | c.5136G>T p.G1712= | Silent (SNP) | VAF 14/199 reads (7%) | catalogued as COSV53108801; called by muse, mutect2
- FER1L5 | c.5277G>A p.L1759= (on ENST00000623019; = p.L1723= on NM_001293083.2) | Silent (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- FER1L6 | c.4005C>T p.S1335= | Silent (SNP) | VAF 38/287 reads (13%) | catalogued as rs1421340282; called by muse, mutect2, varscan2
- FRMPD4 | c.237G>A p.V79= | Silent (SNP) | VAF 39/392 reads (10%) | called by muse, mutect2, varscan2
- GABRE | c.1482C>T p.F494= | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- GALNT9 | c.1473C>T p.Y491= (on ENST00000328957 / NM_001122636.2; = p.Y125= on NM_021808.3) | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs756480646; called by muse, mutect2, varscan2
- GDPD2 | c.180C>T p.V60= | Silent (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- GHR | c.1818C>T p.G606= | Silent (SNP) | VAF 61/534 reads (11%) | catalogued as rs747589492; called by muse, mutect2, varscan2
- GLYR1 | c.1644C>T p.Y548= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as rs765919964; called by muse, mutect2, varscan2
- GREB1L | c.3405G>A p.E1135= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as COSV52553034; called by muse, mutect2, varscan2
- GRIK1 | c.789T>C p.F263= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2
- HMOX2 | c.147A>G p.E49= | Silent (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- HOXB1 | c.720G>T p.L240= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- HRH2 | c.445C>T p.L149= | Silent (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- IFRD2 | c.1341C>T p.L447= | Silent (SNP) | VAF 25/182 reads (14%) | called by muse, mutect2, varscan2
- IQCH | c.2760C>T p.L920= | Silent (SNP) | VAF 65/362 reads (18%) | called by muse, mutect2, varscan2
- ITGAX | c.1800G>T p.V600= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- KBTBD4 | c.1305G>A p.V435= | Silent (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- KIAA1549 | c.4107G>A p.L1369= | Silent (SNP) | VAF 11/227 reads (5%) | called by muse, mutect2
- LRP1B | c.2634A>T p.S878= | Silent (SNP) | VAF 30/332 reads (9%) | catalogued as rs774760516; called by muse, mutect2
- LRTOMT | c.30G>A p.S10= | Silent (SNP) | VAF 69/576 reads (12%) | catalogued as rs148745596; called by muse, mutect2, varscan2
- MED25 | c.639G>A p.V213= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV57207886; called by muse, mutect2
- MTNR1B | c.744G>A p.R248= | Silent (SNP) | VAF 39/350 reads (11%) | catalogued as rs1257047833, COSV99925211; called by muse, mutect2, varscan2
- MYO9B | c.2949C>T p.A983= | Silent (SNP) | VAF 19/221 reads (9%) | catalogued as rs556000766; called by muse, mutect2
- NACC1 | c.1311C>T p.L437= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- NAPSA | c.816T>A p.T272= | Silent (SNP) | VAF 30/302 reads (10%) | called by muse, mutect2
- NCF1 | c.129C>A p.R43= | Silent (SNP) | VAF 56/396 reads (14%) | called by muse, mutect2, varscan2
- NDUFV2 | c.6C>T p.F2= | Silent (SNP) | VAF 25/298 reads (8%) | catalogued as rs547252886; ClinVar: uncertain significance; called by muse, mutect2
- NF1 | c.6753C>G p.V2251= (on ENST00000358273 / NM_001042492.3; = p.V2230= on NM_000267.3) | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- NID1 | c.2322G>T p.R774= | Silent (SNP) | VAF 32/494 reads (6%) | called by muse, mutect2
- NIPBL | c.4272G>T p.V1424= | Silent (SNP) | VAF 11/175 reads (6%) | called by muse, mutect2
- NLRP10 | c.546C>A p.L182= | Silent (SNP) | VAF 38/446 reads (9%) | catalogued as rs768045821, COSV100149679; called by muse, mutect2
- NR2F6 | c.705G>T p.L235= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- NXF3 | c.1545C>A p.S515= | Silent (SNP) | VAF 43/380 reads (11%) | called by muse, mutect2, varscan2
- OR2F1 | c.165C>A p.L55= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as COSV67331808; called by muse, mutect2
- OR2M3 | c.657T>G p.A219= | Silent (SNP) | VAF 26/810 reads (3%) | catalogued as COSV101513412; called by muse, mutect2
- OR6N1 | c.130C>T p.L44= | Silent (SNP) | VAF 22/549 reads (4%) | catalogued as COSV58648400; called by muse, mutect2
- OR8J3 | c.474G>T p.V158= | Silent (SNP) | VAF 26/398 reads (7%) | called by muse, mutect2
- PCDHA12 | c.1845G>T p.A615= | Silent (SNP) | VAF 33/291 reads (11%) | catalogued as rs535177109, COSV56506793; called by muse, mutect2, varscan2
- PCDHA5 | c.492T>C p.N164= | Silent (SNP) | VAF 48/552 reads (9%) | called by muse, mutect2
- PCDHB11 | c.1920G>T p.L640= | Silent (SNP) | VAF 30/547 reads (5%) | called by muse, mutect2
- PCDHB13 | c.1878C>A p.T626= | Silent (SNP) | VAF 44/507 reads (9%) | catalogued as COSV53401846; called by muse, mutect2, varscan2
- PDGFRB | c.1596G>A p.V532= | Silent (SNP) | VAF 34/329 reads (10%) | catalogued as rs1309800597; called by muse, mutect2, varscan2
- PIK3CG | c.831G>T p.R277= | Silent (SNP) | VAF 51/551 reads (9%) | catalogued as COSV63249232; called by muse, mutect2
- PIK3R2 | c.1059A>T p.L353= | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- POF1B | c.81C>A p.P27= | Silent (SNP) | VAF 90/670 reads (13%) | catalogued as COSV53133912; called by muse, mutect2, varscan2
- PRKCH | c.183G>A p.Q61= | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as COSV60649632; called by muse, mutect2, varscan2
- PTGER4 | c.1303C>A p.R435= | Silent (SNP) | VAF 36/290 reads (12%) | catalogued as rs765298065; called by muse, mutect2, varscan2
- PTH1R | c.768C>A p.L256= | Silent (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- PTPRM | c.3777C>T p.V1259= | Silent (SNP) | VAF 11/279 reads (4%) | called by muse, mutect2
- SKAP2 | c.93A>T p.I31= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs938988973; called by muse, varscan2
- SLC18A2 | c.945G>T p.L315= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1419C>A p.A473= | Silent (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- SORCS3 | c.2652G>A p.K884= | Silent (SNP) | VAF 54/580 reads (9%) | called by muse, mutect2
- SOST | c.598C>A p.R200= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs769015314; called by muse, mutect2, varscan2
- SOX5 | c.1128A>G p.T376= | Silent (SNP) | VAF 97/557 reads (17%) | called by muse, mutect2, varscan2
- SUMF2 | c.120G>A p.K40= (on ENST00000652303; = p.K21= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/366 reads (10%) | catalogued as COSV51904113; called by muse, mutect2, varscan2
- TEX15 | c.3261C>A p.T1087= (on ENST00000256246; = p.T1470= on NM_001350162.2) | Silent (SNP) | VAF 17/201 reads (8%) | called by muse, mutect2
- TRAJ26 | c.42C>A p.T14= | Silent (SNP) | VAF 36/434 reads (8%) | called by muse, mutect2
- TRPC4 | c.717G>A p.S239= | Silent (SNP) | VAF 36/478 reads (8%) | catalogued as rs769218068, COSV58995536; called by muse, mutect2
- TTC34 | c.2091A>T p.R697= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- UBXN6 | c.912G>A p.Q304= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- VCAN | c.1395C>A p.G465= | Silent (SNP) | VAF 58/584 reads (10%) | catalogued as rs772684866, COSV54102683; called by muse, mutect2, varscan2
- VWA3A | c.3207C>A p.V1069= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- VWA5B1 | c.1017C>A p.V339= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- WNT6 | c.417G>T p.G139= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- XIRP1 | c.3132G>T p.P1044= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV100454083, COSV61139514; called by muse, mutect2, varscan2
- ZBED1 | c.432G>T p.V144= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- ZNF492 | c.1230A>G p.T410= | Silent (SNP) | VAF 22/387 reads (6%) | catalogued as rs1427694007; called by muse, mutect2
- ZNF502 | c.1419T>A p.A473= | Silent (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- ZPBP2 | c.912T>C p.F304= (on ENST00000348931 / NM_199321.3; = p.F282= on NM_198844.3) | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs771371586; called by muse, mutect2, varscan2
- ABCA5 | c.2764+12_2764+13del | Intron (DEL) | VAF 15/75 reads (20%) | called by pindel, varscan2
- ABCB7 | chrX:75156724 C>A | 5'Flank (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- AC008060.1 | n.283C>A | RNA (SNP) | VAF 41/491 reads (8%) | called by muse, mutect2
- ADAM7 | c.2209-1359C>T | Intron (SNP) | VAF 31/303 reads (10%) | called by muse, mutect2, varscan2
- ANO1 | c.-28C>G | 5'UTR (SNP) | VAF 14/114 reads (12%) | catalogued as rs1430011197, COSV62444754; called by muse, mutect2, varscan2
- ARHGAP22 | c.323-13748G>T | Intron (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2, varscan2
- ATP6AP2 | c.738+13G>T | Intron (SNP) | VAF 42/508 reads (8%) | called by muse, mutect2
- AURKC | c.58+36G>T | Intron (SNP) | VAF 60/315 reads (19%) | catalogued as COSV57138815; called by muse, mutect2, varscan2
- BACE2 | c.312+10740G>T | Intron (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- BEND6 | chr6:56954449 G>A | 5'Flank (SNP) | VAF 61/275 reads (22%) | called by muse, mutect2, varscan2
- C2CD3 | c.1843+147A>G | Intron (SNP) | VAF 18/126 reads (14%) | catalogued as rs774018530; called by muse, mutect2
- CCL15 | c.-1G>A | 5'UTR (SNP) | VAF 34/305 reads (11%) | catalogued as rs371351294; called by muse, varscan2
- CLDN19 | c.626+101C>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- CSHL1 | c.472-55G>T | Intron (SNP) | VAF 66/692 reads (10%) | catalogued as COSV99367818; called by muse, mutect2
- DNAI2 | c.1211+1822G>A | Intron (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- DPYS | c.*14+14G>T | Intron (SNP) | VAF 50/412 reads (12%) | called by muse, mutect2, varscan2
- ENTPD5 | c.218-179C>T | Intron (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7312C>G | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009610 del G | 5'Flank (DEL) | VAF 38/416 reads (9%) | called by mutect2, pindel
- F12 | c.1387+11del | Intron (DEL) | VAF 23/188 reads (12%) | called by mutect2, pindel, varscan2
- FAM90A27P | n.920C>A | RNA (SNP) | VAF 34/240 reads (14%) | called by muse, mutect2, varscan2
- FBN2 | c.952+20G>T | Intron (SNP) | VAF 25/343 reads (7%) | called by muse, mutect2
- FER1L4 | n.3553G>A | RNA (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- FRMD1 | c.870+187C>A | Intron (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- GALNT14 | c.129+12778C>A | Intron (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- GPAT2 | c.1358-15C>T | Intron (SNP) | VAF 37/201 reads (18%) | catalogued as rs370616408; called by muse, mutect2, varscan2
- GUSBP10 | n.316C>G | RNA (SNP) | VAF 31/328 reads (9%) | called by muse, mutect2
- HDAC5 | c.2607+30G>T | Intron (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- IDS | c.1007-174C>A | Intron (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- IGSF22 | c.2095+1469C>A | Intron (SNP) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- KCTD7 | c.*24del | 3'UTR (DEL) | VAF 35/345 reads (10%) | called by mutect2, pindel, varscan2
- LBR | c.1565-18A>G | Intron (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- LILRA4 | c.*9G>A | 3'UTR (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- MACROH2A1 | c.953+26C>G | Intron (SNP) | VAF 45/401 reads (11%) | called by muse, mutect2, varscan2
- MAPKAPK2 | chr1:206682981 C>G | 5'Flank (SNP) | VAF 21/389 reads (5%) | catalogued as rs575112374; called by muse, mutect2
- MYLK2 | c.-8C>T | 5'UTR (SNP) | VAF 42/520 reads (8%) | called by muse, mutect2
- NDUFB10 | chr16:1965325 C>A | 3'Flank (SNP) | VAF 15/92 reads (16%) | catalogued as rs780279301; called by muse, mutect2, varscan2
- NOC2LP2 | n.726G>T | RNA (SNP) | VAF 47/416 reads (11%) | called by muse, mutect2, varscan2
- NSD1 | c.-3A>T | 5'UTR (SNP) | VAF 18/243 reads (7%) | called by muse, mutect2
- NXF3 | c.*16C>A | 3'UTR (SNP) | VAF 34/397 reads (9%) | catalogued as COSV67702650; called by muse, mutect2
- OBSCN | c.11659+3527G>T | Intron (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- OR52B1P | n.226G>A | RNA (SNP) | VAF 21/289 reads (7%) | called by muse, mutect2
- OR6W1P | n.425G>A | RNA (SNP) | VAF 8/158 reads (5%) | catalogued as rs780909962; called by muse, mutect2
- RNA5-8SP2 | chr16:34159172 G>T | 5'Flank (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.395G>T | RNA (SNP) | VAF 86/751 reads (11%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36603C>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs1440997083, COSV61204726; called by muse, mutect2
- SKOR2 | c.2753-143G>T | Intron (SNP) | VAF 18/262 reads (7%) | catalogued as rs947232889; called by muse, mutect2
- SLC4A8 | c.2172+4917T>A | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3622G>A | RNA (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- ST8SIA3 | c.-30C>A | 5'UTR (SNP) | VAF 46/457 reads (10%) | catalogued as COSV100129707; called by muse, mutect2, varscan2
- SYN2 | c.1369+52A>T | Intron (SNP) | VAF 32/409 reads (8%) | called by muse, mutect2
- TRBV21OR9-2 | n.228A>G | RNA (SNP) | VAF 20/224 reads (9%) | catalogued as rs1272656233; called by muse, mutect2
- TSPAN7 | c.82-43116A>T | Intron (SNP) | VAF 38/243 reads (16%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-12167T>A | Intron (SNP) | VAF 32/312 reads (10%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3500C>A | Intron (SNP) | VAF 21/196 reads (11%) | catalogued as rs1436718883; called by muse, mutect2, varscan2
- ZNF76 | c.1608+31C>T | Intron (SNP) | VAF 89/515 reads (17%) | called by muse, mutect2, varscan2
